Surgical pathology report (de-identified scan), TCGA case TCGA-N6-A4VG, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site University of Pittsburgh, specimen TCGA-N6-A4VG-01A (Primary Tumor).

[page 1 of 2]
Collection Date:

FINAL DIAGNOSIS:

PART 1: SIGMOID NODULE, EXCISION -

ADENOCARCINOMA, CLEAR CELL TYPE, 7 MM.

PART 2: UTERUS AND CERVIX (156 GRAMS) WITH BILATERAL ADNEXA, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY -

- A. MALIGNANT MIXED MULLERIAN TUMOR OF ENDOMETRIUM WITH HIGH GRADE CARCINOMATOUS COMPONENT.
- B. NEOPLASM INVADES MYOMETRIUM UP TO 20%.
- C. EXTENSIVE LYMPHOVASCULAR INVASION BY HIGH GRADE CARCINOMA.
- D. HIGH GRADE ADENOCARCINOMA EXTENDS INTO CERVICAL STROMA.
- E. ADENOCARCINOMA IN SEROSA OF UTERUS.
- F. PATHOLOGIC STAGE: pT3 pN2 Mx.
- G. BACKGROUND ENDOMETRIUM IS ATROPHIC.
- H. LEIOMYOMAS MEASURING UP TO 1.8 CM.
- I. RIGHT FALLOPIAN TUBE WITH SEROSAL IMPLANTS OF HIGH GRADE ADENOCARCINOMA.
- J. RIGHT PARATUBAL CYST.
- K. RIGHT OVARY WITH ADENOCARCINOMA IN CORTICAL ADHESIONS.
- L. LEFT FALLOPIAN TUBE WITH PARATUBAL CYST, NO NEOPLASM IDENTIFIED.
- M. LEFT OVARY WITH CALCIFIED CORPORA ALBICANS, NO NEOPLASM IDENTIFIED.

PART 3: CUL-DE-SAC NODULE, EXCISION -
ADENOCARCINOMA, 2 MM.

PART 4: LYMPH NODES, LEFT PELVIC, DISSECTION -
TWO LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/2).

PART 5: LYMPH NODES, LEFT COMMON, DISSECTION -
ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 6: LYMPH NODES, RIGHT PELVIC, DISSECTION -
A. TWO LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA (2/2).
B. NO EXTRACAPSULAR EXTENSION IDENTIFIED.

PART 7: LYMPH NODES, RIGHT COMMON, DISSECTION -
ADIPOSE TISSUE, NO LYMPH NODES OR NEOPLASM IDENTIFIED.

PART 8: LYMPH NODES, RIGHT PERIAORTIC, DISSECTION -
A. ONE OF TWO LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA (1/2).
B. NO EXTRACAPSULAR EXTENSION IDENTIFIED.

PART 9: SIGMOID NODULE #2, EXCISION -
ADENOCARCINOMA, 5 MM.

PART 10: APPENDIX, APPENDECTOMY -
UNREMARKABLE APPENDIX.

PART 11: OMENTUM, OMENTECTOMY -
MULTIPLE FOCI OF ADENOCARCINOMA MEASURING UP TO 5 MM.

PART 12: CECUM, NODULE, EXCISION -
ADENOCARCINOMA, 6.5 MM.

COMMENT:

The high grade component is predominantly serous with focal clear cell areas. Findings correlate with companion pelvic wash cytology interpreted as positive.

FLD-0-3

*Carcinocarcinoma / Mixed
Mullerian Tumor, malignant
8456/3
Site: Corpus Uteri,
Endometrium C04.1*

JW 3/28/13

[page 2 of 2]
Addendum
ER and PR were performed on block 2G with the following results.

****SUMMARY OF BREAST TUMOR IMMUNOHISTOLOGY RESULTS****

HORMONE RECEPTOR IMMUNOHISTOCHEMISTRY

	RESULT	H-SCORE
ESTROGEN	Positive	20
PROGESTERONE	Positive	40

*Mean ER H Scores vs Percent Cells Staining: 251 (>75%); 130 (51-75%); 42 (10-50%); 4 (<10%)

ESTROGEN/PROGESTERONE RECEPTORS IMMUNOHISTOCHEMICAL REPORT

Using formalin fixed tissues (8-96 hours) and appropriate positive and negative internal/external controls; the test for the presence of these hormone receptor proteins is performed by the immunoperoxidase method according to the ASCO-CAP Guidelines. A positive Estrogen or Progesterone receptor tumor shows nuclear immunostaining in greater than or equal to 1% of the tumor cells and the semiquantitation immunostaining raw data is indicated below. The ER and PR Histologic Score (H-Score, or HS) is calculated as the sum of intensity of staining times the proportion of cells staining and has a dynamic range of 0 to 300.

	Result	H Score	Raw Immunostaining Semiquantitation
ER:	Positive	20	(0 80%; 1+ 20%; 2+ 0%; 3+ 0%)
PR:	Positive	40	(0 75%; 1+ 10%; 2+ 15%; 3+ 0%)

Estrogen receptor antibody SP1, an IVD, is performed using the IVIEW detection

Progesterone receptor antibody 1E2, an IVD, is performed using the IVIEW detection

CASE SYNOPSIS:
SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL CARCINOMA & CARCINOSARCOMA : HYSTERECTOMY

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL CARCINOMATOUS SPECIMENS

SPECIMENS

TUMOR TYPE: Carcinosarcoma (malignant mixed Mullerian tumor)

TUMOR TYPE: Carcinoma, endometrial
TUMOR SIZE: Maximum dimension: 40 mm

TUMOR SIZE: _____ **INTRAUTERINE EXTENSION:** _____
PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT: _____

Anterior endomyometrium: 25 %, Posterior endomyometrium: 50 %

DEPTH OF INVASION: Less than 1/2 thickness of myometrium

STRUCTURES INVOLVED: Cervical stroma, Adnexa, Uterine serosa

ANGIOLYMPHATIC INVASION: Yes

OTHER: Leiomyoma

LYMPH NODES POSITIVE: Number of lymph nodes positive:: 3

LYMPH NODES POSITIVE: 1
LYMPH NODES EXAMINED: 7

LYMPH NODE GROUPS INVOLVED: Pelvic lymph nodes, Right, Para-aortic lymph nodes, Right

LYMPH NODE GROUPS INVOLVED: No
EXTRANODAL EXTENSION: No

EXTRANODAL EXTENSION: NO
T STAGE, PATHOLOGIC: pT3a

N STAGE. PATHOLOGIC: pN2

M STAGE, PATHOLOGIC: Not applicable

FIGO STAGE: IVB

Duplicate Discrepancy		✓
1st/2nd Discrepancy		✓
Primary Malignancy History		✓
Qualifying Franchises Primary National		✓

Source: NCI Genomic Data Commons file eec94a78-7e03-4e16-931e-55ceb59917c1 (TCGA-N6-A4VG.830AA97A-8A14-49D9-85C6-F48C41E90C1D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).